Somatic mutation profile of tumor specimen ALCH-ADUO-TTP1-A (aliquot ALCH-ADUO-TTP1-A-1-0-D-A587-36) from ALCHEMIST case ALCH-ADUO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.0 years (23,360 days).
Specimen ALCH-ADUO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22da84dc-4e4c-4ede-869f-83e6022b60da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADUO-NB1-A (Blood Derived Normal), aliquot ALCH-ADUO-NB1-A-1-0-D-A587-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40f98381-468c-43a5-ab7e-6b312e296e0d

The open-access MAF lists 138 somatic variants for this specimen: 98 protein-altering or splice-affecting, 30 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 30, Frame Shift Del 6, Intron 6, Nonsense Mutation 5, Splice Region 3, In Frame Del 2, Translation Start Site 2, Splice Site 2, Frame Shift Ins 2, RNA 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 938/1675 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 149/379 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATK | c.3703_3705del p.F1235del (on ENST00000326724 / NM_001080395.3; = p.F1132del on NM_004920.2) | In Frame Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs1436522950; called by pindel, varscan2
- ALAS2 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs752853849, COSV58188274, COSV58190561; called by muse, mutect2, varscan2
- ANKRD2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749768287, COSV53967380; called by muse, mutect2
- CLPSL1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 50/391 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs746478457; called by mutect2, varscan2
- CT47B1 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 61/652 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as rs749011334, COSV64890387; called by muse, mutect2
- CTNNA1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs746153198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLG5 | c.2294A>G p.N765S | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs777590917; called by muse, mutect2, varscan2
- ENTR1 | c.1097A>C p.N366T (on ENST00000357365 / NM_001039707.2; = p.N343T on NM_006643.4) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53743803; called by muse, mutect2, varscan2
- EXOC5 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1255225971, COSV100566990; called by muse, mutect2, varscan2
- F9 | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 147/467 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as CM045762, CM940452; called by muse, mutect2, varscan2
- FUCA2 | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 198/456 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs763661877; called by muse, varscan2
- FYB1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 118/551 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.134); catalogued as rs764819701, COSV100685218; called by muse, mutect2, varscan2
- GAB4 | c.686+1G>T p.X229_splice | Splice Site (SNP) | VAF 127/250 reads (51%) | catalogued as rs200250480, COSV101272061; called by muse, mutect2, varscan2
- GPR12 | c.458C>A p.T153K | Missense Mutation (SNP) | VAF 156/410 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67344317; called by muse, mutect2, varscan2
- ITGAE | c.2071A>T p.S691C | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as rs1567529660; called by muse, mutect2, varscan2
- KCNA6 | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 50/219 reads (23%) | catalogued as COSV99768506; called by muse, mutect2, varscan2
- LRP12 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1202697745, COSV52627165, COSV52628007; called by muse, mutect2, varscan2
- MED25 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs767471143; called by muse, mutect2, varscan2
- PTPRZ1 | c.2759G>T p.R920L | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV66442776; called by muse, mutect2, varscan2
- RBM10 | c.2327G>C p.R776P | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100238382; called by muse, mutect2, varscan2
- SDK1 | c.5102C>T p.P1701L | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371544471; called by muse, mutect2, varscan2
- SLIT2 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs80248215, COSV56561255; called by muse, mutect2, varscan2
- SPAG1 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs770542001; called by muse, varscan2
- SPIN3 | c.364A>C p.T122P | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.078); catalogued as COSV100888456; called by muse, mutect2, varscan2
- STRA6 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60584634; called by muse, mutect2, varscan2
- TAFA1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 33/156 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV72039864; called by muse, mutect2, varscan2
- TTF1 | c.173A>T p.D58V | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs781320000; called by muse, mutect2, varscan2
- XPNPEP2 | c.338C>A p.T113N | Missense Mutation (SNP) | VAF 91/492 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64368028; called by muse, mutect2, varscan2
- ZFHX4 | c.1081C>A p.R361S | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.994); catalogued as COSV51491941; called by muse, mutect2, varscan2
- ZFHX4 | c.7621G>C p.D2541H | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as COSV99265264; called by muse, mutect2, varscan2
- ZNF385D | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV55769135; called by muse, mutect2
- ZNF891 | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1231228874; called by muse, mutect2, varscan2
- ABCB5 | c.3751G>C p.V1251L (on ENST00000404938 / NM_001163941.2; = p.V806L on NM_178559.6) | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ACSL4 | c.2126G>T p.G709V (on ENST00000340800 / NM_022977.2; = p.G668V on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/691 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGRN | c.4762G>A p.E1588K | Missense Mutation (SNP) | VAF 29/304 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ALG13 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 92/511 reads (18%) | called by muse, mutect2, varscan2
- ALG2 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK2 | c.2694-2A>G p.X898_splice | Splice Site (SNP) | VAF 18/436 reads (4%) | called by muse, mutect2
- BMP6 | c.1009G>T p.V337F | Missense Mutation (SNP) | VAF 77/128 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CADM2 | c.271G>T p.V91F (on ENST00000407528 / NM_001167674.2; = p.V93F on NM_153184.4) | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- CD163L1 | c.3676C>A p.P1226T | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC23 | c.186_191dup p.P63_A64dup | In Frame Ins (INS) | VAF 22/172 reads (13%) | called by mutect2, pindel, varscan2
- CEP170 | c.3825G>T p.M1275I | Missense Mutation (SNP) | VAF 76/745 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CFAP46 | c.3372G>T p.Q1124H | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLEC17A | c.402G>T p.L134= | Splice Region (SNP) | VAF 51/287 reads (18%) | called by muse, mutect2, varscan2
- CYP27C1 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 149/497 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- DARS1 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DIDO1 | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 40/958 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH1 | c.2262C>A p.Y754* | Nonsense Mutation (SNP) | VAF 27/122 reads (22%) | called by muse, mutect2, varscan2
- ETNPPL | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FBXO40 | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GABRR3 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 20/537 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2
- GALNT3 | c.237_238del p.K79Nfs*12 | Frame Shift Del (DEL) | VAF 93/602 reads (15%) | called by mutect2, pindel, varscan2
- GJB3 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 32/694 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- GPR37L1 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIPK1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HJURP | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGLV2-8 | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 360/802 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- IRGC | c.1256G>T p.S419I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ITGB5 | c.1652A>T p.D551V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF2C | c.77T>C p.I26T | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- KRTAP19-3 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 119/550 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA3 | c.3833G>A p.C1278Y | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP2 | c.12880_12882del p.V4294del | In Frame Del (DEL) | VAF 93/385 reads (24%) | called by mutect2, pindel, varscan2
- MMEL1 | c.617G>T p.W206L | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH11 | c.5334C>A p.S1778R | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- MYO9A | c.2286C>G p.C762W | Missense Mutation (SNP) | VAF 59/411 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NACA2 | c.430A>T p.R144* | Nonsense Mutation (SNP) | VAF 114/909 reads (13%) | called by muse, mutect2, varscan2
- NLGN4X | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10G8 | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- OXGR1 | c.322T>C p.F108L | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PLCG1 | c.1149_1150del p.L384Yfs*30 | Frame Shift Del (DEL) | VAF 158/468 reads (34%) | called by mutect2, pindel, varscan2
- PRC1 | c.1481C>G p.S494C | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PRDM2 | c.1908_1909delinsT p.K637Rfs*29 | Frame Shift Del (DEL) | VAF 19/192 reads (10%) | called by pindel, varscan2*
- RADX | c.1866C>G p.S622R | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- RALGAPA2 | c.5382del p.P1795Lfs*7 | Frame Shift Del (DEL) | VAF 54/231 reads (23%) | called by pindel, varscan2
- RELN | c.2933C>T p.T978I | Missense Mutation (SNP) | VAF 69/470 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SDK2 | c.6288G>T p.R2096S | Missense Mutation (SNP) | VAF 169/388 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SHROOM4 | c.2551C>G p.Q851E | Missense Mutation (SNP) | VAF 85/674 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC22A10 | c.1002A>T p.K334N | Missense Mutation (SNP) | VAF 225/585 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- SLC6A14 | c.1282A>G p.I428V | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by mutect2, varscan2
- SPI1 | c.716del p.G239Afs*6 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | called by mutect2, pindel
- SYMPK | c.2893+3G>A | Splice Region (SNP) | VAF 77/357 reads (22%) | called by muse, mutect2, varscan2
- SYNPO | c.851dup p.N284Kfs*22 (on ENST00000394243 / NM_001166208.2; = p.N40Kfs*22 on NM_007286.6) | Frame Shift Ins (INS) | VAF 121/447 reads (27%) | called by mutect2, pindel, varscan2
- TAGAP | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TANC1 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 53/476 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TMTC1 | c.839C>A p.P280H (on ENST00000539277 / NM_001193451.2; = p.P172H on NM_175861.3) | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- TNFRSF8 | c.420A>T p.P140= | Splice Region (SNP) | VAF 80/164 reads (49%) | called by muse, mutect2, varscan2
- USP11 | c.2399G>T p.W800L (on ENST00000218348; = p.W757L on NM_001371072.1) | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP9X | c.3099G>A p.M1033I | Missense Mutation (SNP) | VAF 44/474 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- VPS13D | c.5147del p.V1716Gfs*45 | Frame Shift Del (DEL) | VAF 40/400 reads (10%) | called by mutect2, pindel, varscan2
- ZNF568 | c.1898A>T p.E633V | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF679 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 45/265 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF679 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- ZNF79 | c.836dup p.C279Wfs*5 | Frame Shift Ins (INS) | VAF 24/183 reads (13%) | called by mutect2, pindel, varscan2
- ZZEF1 | c.6114G>C p.Q2038H | Missense Mutation (SNP) | VAF 25/322 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.054); called by muse, mutect2
- ANKRD30A | c.3894T>A p.A1298= (on ENST00000611781; = p.A1242= on NM_052997.2) | Silent (SNP) | VAF 56/315 reads (18%) | catalogued as COSV100654535; called by muse, mutect2, varscan2
- CACNA1G | c.2031G>A p.E677= | Silent (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- CEP170 | c.3378T>C p.S1126= | Silent (SNP) | VAF 38/392 reads (10%) | called by muse, mutect2, varscan2
- CHST1 | c.219C>T p.S73= | Silent (SNP) | VAF 30/282 reads (11%) | catalogued as rs746968239; called by muse, mutect2
- DAG1 | c.1953C>A p.T651= | Silent (SNP) | VAF 12/292 reads (4%) | catalogued as COSV100445093; called by muse, mutect2
- DBX1 | c.450C>A p.I150= | Silent (SNP) | VAF 129/309 reads (42%) | called by muse, mutect2, varscan2
- FAM71B | c.936G>T p.A312= | Silent (SNP) | VAF 106/296 reads (36%) | catalogued as rs112099847; called by muse, mutect2, varscan2
- GATA2 | c.1296C>A p.A432= | Silent (SNP) | VAF 30/210 reads (14%) | called by muse, mutect2, varscan2
- GCN1 | c.789G>T p.L263= | Silent (SNP) | VAF 63/222 reads (28%) | called by muse, mutect2, varscan2
- GPATCH2L | c.735C>T p.D245= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs772258899, COSV55048257; called by muse, mutect2
- H2BW1 | c.306C>T p.A102= | Silent (SNP) | VAF 40/454 reads (9%) | catalogued as rs1234537985; called by muse, mutect2
- HELLS | c.1191A>G p.L397= | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- HSFX1 | c.198C>A p.I66= | Silent (SNP) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- IFNA21 | c.429G>A p.V143= | Silent (SNP) | VAF 82/347 reads (24%) | called by muse, mutect2, varscan2
- LTBP1 | c.3924C>A p.S1308= (on ENST00000404816 / NM_206943.4; = p.S982= on NM_000627.4) | Silent (SNP) | VAF 68/478 reads (14%) | called by muse, mutect2, varscan2
- MGAM | c.5043C>G p.R1681= | Silent (SNP) | VAF 61/375 reads (16%) | catalogued as COSV72074600; called by muse, mutect2, varscan2
- MUC16 | c.6069A>G p.G2023= | Silent (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- OR13D1 | c.150C>A p.S50= | Silent (SNP) | VAF 32/185 reads (17%) | called by muse, mutect2, varscan2
- PCDH15 | c.1824A>G p.P608= | Silent (SNP) | VAF 95/605 reads (16%) | called by muse, mutect2, varscan2
- PLA2G4F | c.1359C>T p.G453= | Silent (SNP) | VAF 42/339 reads (12%) | catalogued as rs1416008742; called by muse, mutect2, varscan2
- PSMB9 | c.450C>T p.G150= | Silent (SNP) | VAF 56/465 reads (12%) | called by muse, mutect2, varscan2
- PTH | c.165G>T p.L55= | Silent (SNP) | VAF 122/281 reads (43%) | called by muse, mutect2, varscan2
- RASGRP2 | c.282G>T p.P94= | Silent (SNP) | VAF 87/566 reads (15%) | catalogued as COSV62450058; called by muse, mutect2, varscan2
- SOX4 | c.1329C>T p.H443= | Silent (SNP) | VAF 105/206 reads (51%) | catalogued as rs958601695; called by muse, mutect2, varscan2
- TMCC2 | c.624C>T p.A208= | Silent (SNP) | VAF 33/167 reads (20%) | catalogued as rs753624571; called by muse, mutect2, varscan2
- TMEM125 | c.468C>T p.A156= | Silent (SNP) | VAF 57/401 reads (14%) | called by muse, mutect2, varscan2
- TMSB15A | c.39T>C p.F13= | Silent (SNP) | VAF 32/404 reads (8%) | called by muse, mutect2
- TRAJ52 | c.60T>A p.T20= | Silent (SNP) | VAF 162/442 reads (37%) | catalogued as rs542838254; called by muse, mutect2, varscan2
- ZCCHC18 | c.222T>C p.D74= | Silent (SNP) | VAF 104/253 reads (41%) | called by muse, mutect2, varscan2
- ZNF470 | c.1644G>A p.Q548= | Silent (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2, varscan2
- FBXL7 | c.740-1196del | Intron (DEL) | VAF 93/320 reads (29%) | called by mutect2, pindel, varscan2
- FLJ40288 | n.591G>A | RNA (SNP) | VAF 36/204 reads (18%) | called by muse, mutect2, varscan2
- LARP6 | c.200+1575G>T | Intron (SNP) | VAF 28/158 reads (18%) | called by muse, mutect2, varscan2
- MACF1 | c.543+11602A>G | Intron (SNP) | VAF 60/490 reads (12%) | called by muse, mutect2, varscan2
- MIR376A1 | n.6G>T | RNA (SNP) | VAF 73/522 reads (14%) | called by muse, mutect2, varscan2
- RIMS2 | c.2083+76G>A | Intron (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81108689 A>G | 5'Flank (SNP) | VAF 79/182 reads (43%) | catalogued as rs1320292855; called by muse, mutect2, varscan2
- SLC1A3 | c.181+4189G>A | Intron (SNP) | VAF 54/488 reads (11%) | called by muse, mutect2, varscan2
- SPAG6 | c.121+120del | Intron (DEL) | VAF 44/305 reads (14%) | called by mutect2, pindel, varscan2
- TAFA4 | c.-35C>A | 5'UTR (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
